Gene-level copy-number profile of tumor specimen TCGA-D8-A145-01A from TCGA case TCGA-D8-A145, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.2 years (29,280 days).
Specimen TCGA-D8-A145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6afb99b2-188d-4de2-9d42-821be341609d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A145-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8cbd46b8-f5c7-4a6b-b72a-945223fb0710

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 2,114; copy number 2: 49,428; copy number 3: 8,251.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A145-01A-11D-A111-01): tumor purity 0.38, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:24,330,402–25,697,188, 27 genes: HMGN2P20, RPL36AP13, AC093798.1, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA, EFR3B, RN7SL856P, SUCLA2P3, POMC, LINC01381, DNMT3A, MIR1301, ARNILA, DTNB, DTNB-AS1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
